Somatic mutation profile of tumor specimen TCGA-DU-6399-01A (aliquot TCGA-DU-6399-01A-12D-1705-08) from TCGA case TCGA-DU-6399, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 54.5 years (19,906 days).
Specimen TCGA-DU-6399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf47967b-4cbc-4a24-99e4-f77038db1f65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6399-10A (Blood Derived Normal), aliquot TCGA-DU-6399-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cdd7686-9819-4b8d-956e-7067f1cc3d14

The open-access MAF lists 56 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Frame Shift Del 3, 5'Flank 1, 3'UTR 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53032869; called by muse, mutect2
- TP53 | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039483, CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ADGRA3 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV51566211; called by muse, mutect2, varscan2
- ALX1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57493454; called by muse, mutect2, varscan2
- ANKRD11 | c.4414G>A p.E1472K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.2); catalogued as COSV56364055; called by muse, mutect2, varscan2
- ANKRD30A | c.4052C>A p.T1351K (on ENST00000611781; = p.T1295K on NM_052997.2) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs752970745, COSV64616399; called by muse, mutect2, varscan2
- AURKA | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV57169446; called by muse, mutect2, varscan2
- BNIP5 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs372110549; called by muse, mutect2, varscan2
- DMD | c.5321G>A p.G1774E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV63776923; called by muse, mutect2, varscan2
- DNAH2 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV66723248; called by muse, mutect2, varscan2
- DNAH9 | c.11791A>G p.N3931D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52364631; called by muse, mutect2, varscan2
- ESR2 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs368924653; called by muse, mutect2, varscan2
- FILIP1 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs200076124; called by muse, mutect2, varscan2
- FRK | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs377628003; called by muse, mutect2
- GPKOW | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs148737160, COSV50242500; called by muse, mutect2
- HCRTR2 | c.1212del p.K405Sfs*3 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as COSV63797228; called by mutect2, pindel, varscan2
- HMCN1 | c.2723C>T p.T908I | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.664); catalogued as COSV54922705; called by muse, mutect2, varscan2
- LMX1A | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs748760314, COSV54225129, COSV99672106; called by muse, mutect2, varscan2
- MAST2 | c.962A>G p.K321R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.631); catalogued as rs748036866, COSV63620255; called by muse, mutect2, varscan2
- NEU2 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52093526; called by muse, mutect2, varscan2
- OR13A1 | c.227C>G p.P76R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV100981009, COSV65572971; called by muse, mutect2, varscan2
- OR9G1 | c.848T>G p.M283R | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV56452709; called by muse, mutect2, varscan2
- RAB38 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 20/333 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54714469; called by muse, mutect2
- RP1 | c.5180A>G p.D1727G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55122266, COSV99606739; called by muse, mutect2
- SCN7A | c.1849A>G p.M617V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs768166683, COSV69270026, COSV69273494; called by muse, mutect2, varscan2
- SERPINB7 | c.494C>A p.S165* | Nonsense Mutation (SNP) | VAF 7/110 reads (6%) | catalogued as COSV60535064; called by muse, mutect2
- SLC22A2 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769783921, COSV65267224; called by muse, mutect2, varscan2
- TC2N | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV61746165, COSV61747755; called by muse, mutect2, varscan2
- TFRC | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV64055799; called by muse, mutect2, varscan2
- THSD7B | c.3233T>A p.L1078Q (on ENST00000272643; = p.L1076Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as COSV55716363; called by muse, mutect2
- ULK2 | c.1067T>G p.V356G | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64447274; called by muse, mutect2, varscan2
- WIPI2 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as rs765792758, COSV56590336; called by muse, mutect2, varscan2
- XKR9 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749042884, COSV68772522; called by muse, mutect2, varscan2
- XPNPEP1 | c.572A>G p.E191G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1185187828, COSV59170021; called by mutect2, varscan2
- ZMPSTE24 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65639908; called by muse, mutect2, varscan2
- ZNF280A | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773690014, COSV57481562; called by muse, mutect2, varscan2
- ZNF292 | c.3214G>C p.A1072P | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV60543646; called by muse, mutect2
- ATRX | c.884del p.K295Rfs*4 | Frame Shift Del (DEL) | VAF 71/109 reads (65%) | called by mutect2, pindel, varscan2
- KRT5 | c.1360C>A p.Q454K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SUPT20HL1 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2
- TP53 | c.839_857del p.R280Kfs*59 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- C3 | c.4764C>A p.I1588= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV55577653; called by muse, mutect2, varscan2
- CLDN6 | c.216G>A p.A72= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs773722719, COSV58508821, COSV58510530; called by muse, mutect2, varscan2
- IFNAR2 | c.597G>A p.K199= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs1362875148, COSV59750238; called by muse, mutect2, varscan2
- KRTAP12-2 | c.60C>T p.C20= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV59972144; called by muse, mutect2, varscan2
- LDLRAD4 | c.618G>A p.R206= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV63340742; called by muse, mutect2, varscan2
- MCF2 | c.2133A>G p.T711= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV58490796; called by muse, mutect2, varscan2
- MUC16 | c.17046C>T p.P5682= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1181519264, COSV67473151; called by muse, mutect2, varscan2
- OR9G4 | c.198G>C p.L66= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV57249367; called by muse, mutect2, varscan2
- POSTN | c.1740T>C p.G580= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV65713898; called by muse, mutect2, varscan2
- PPARG | c.1230C>T p.S410= (on ENST00000287820 / NM_015869.5; = p.S380= on NM_005037.7) | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs148844673, COSV55143139; called by muse, mutect2, varscan2
- REEP6 | c.276C>T p.Y92= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1457024997, COSV52014447; called by muse, mutect2
- TNRC6A | c.2304T>C p.D768= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV59367960; called by muse, mutect2, varscan2
- AMFR | c.*618C>T | 3'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99315946; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498330 C>T | 5'Flank (SNP) | VAF 15/28 reads (54%) | catalogued as rs769638220; called by muse, mutect2, varscan2
- ZNF833P | n.910A>G | RNA (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
